Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SU-01A (Primary Tumor).

[page 1 of 2]
Result Date:

Performed By:

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS
C64.9
JW 10/4/13

Surgical Pathology Report

Final

Surgical Pathology Report

DIAGNOSIS:

A. Periaortic and parahilar lymph nodes: Eight lymph nodes, negative for malignancy (0/8).

B. Mass left kidney, resection: Papillary renal cell carcinoma, Fuhrman nuclear grade 2 (of 4), multifocal, the largest tumor measuring 2.0 cm in greatest dimension. The carcinoma focally bulges perinephric adipose tissue, but no invasion of perinephric adipose tissue is identified. The renal parenchymal margin of resection is negative for malignancy. No lymphatic-vascular invasion is identified (see Comment).

DIAGNOSIS COMMENT:

The specimen was inspected grossly with the assistance of . The portion of kidney reveals a markedly dilated collecting system (8-cm cyst), and a small amount of recognizable attached kidney. The collecting system (large cyst) is lined by benign urothelium. The surrounding renal parenchyma is atrophic and contains several papillary renal cell carcinomas, the largest 2.0 cm in greatest dimension. According to the surgeon, the resection specimen was from a duplicated system, with this representing an atrophic lower pole segment. The inked margin of resection contains more functional kidney, which does not show evidence of papillary renal cell carcinoma.

CLINICAL INFORMATION:

Left kidney mass, papillary renal cell on biopsy.

SPECIMEN(S):

A: Peri-aortic and parahilar lymph nodes

B: Mass, left kidney

PRELIMINARY INTRAOPERATIVE DIAGNOSIS:

[page 2 of 2]
Intraoperative Pathologist(s):

A. Left periaortic, parahilar lymph nodes, FS:

FSA1-A2: Negative for carcinoma.

B. Mass, left kidney, FS: Papillary renal cell carcinoma.

GROSS DESCRIPTION:

Performed

A. Received fresh labeled and "left periaortic and parahilar lymph nodes," are multiple pieces of adipose tissue, 5 x 2.5 x 1.2 cm. Within the fat are seven possible lymph nodes. All the lymph nodes are submitted for frozen section in two cassettes labeled -A2.

B. Received fresh labeled and "mass, left kidney," is a 283 g renal mass with attached fat, 14 x 13 x 5 cm. On one of the surfaces is a portion of renal parenchyma, 4 x 3 x 1.2 cm. Attached the renal parenchyma is a large dilated cystic structure, 8 x 8 cm. The cyst wall is tan and smooth. Adjacent to the cyst wall are two separate, well-circumscribed, tan-yellow nodules, 2 x 1.5 x 1.5 cm and 2 x 2 x 1.5 cm. These tumors appear to be subcapsular and do not show any evidence of invading into the fat or through the capsule. No adrenal is identified. A portion of the tumor is submitted for Representative sections are submitted in cassettes labeled : B1) Tissue tumor submitted for frozen section; B2-B3) remainder of tumor #1 submitted for frozen section; B4-B5) second tumor; B6-B8) attached renal parenchyma; B9) vessel margins; B10-B14) sections of dilated cystic structure.

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

. They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

ImPAA Discrepancy		/

Source: NCI Genomic Data Commons file 3f5ca36c-ca3d-4df5-bef8-898c5c43ca4a (TCGA-SX-A7SU.86A05123-38F0-4A96-B383-6CDAC65D6E29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).